Surgical pathology report (de-identified scan), TCGA case TCGA-SI-A71Q, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-A71Q-01A (Primary Tumor).

[page 1 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3

Tumor peripheral nerve
sheath malignant

9540/3

Site Soft tissue Chest
wall C49.3

JW 8/9/13

SURGICAL PATHOLOGY REPORT

* Consult Report *

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Physician(s): [REDACTED]

Service:

Location:

MRN: [REDACTED]

Hospital ID: [REDACTED]

Patient Type: [REDACTED]

Accession: [REDACTED]

Taker:

Received:

Accession:

Reported:

DIAGNOSIS

SOFT TISSUE, LEFT CHEST WALL "MASS," BIOPSY (

- MALIGNANT SPINDLE CELL NEOPLASM, CONSISTENT WITH MALIGNANT PERIPHERAL NERVE
SHEATH TUMOR (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal
examination of the slides (and/or other material submitted in the diagnosis).

***Report Electronically Reviewed and Signed Out B

Microscopic Description and Comment:

Sections of needle core tissue from the chest wall mass show a spindle cell neoplasm with variable cellularity. Tumor cells are arranged in storiform or fascicular patterns. Individual tumor cells are oval to spindle. Frequent mitoses are seen. No necrosis is noted. Focal invasion into skeletal muscle and adipose tissue is noted. The provided immunostains show that tumor cells are diffusely and strongly positive for vimentin, and diffusely positive for CD57. A neurofilament immunostain is positive in a small subset, scattered tumor cells. Keratin smooth muscle actin, NSE, GFAP, and S100 are negative in tumor cells. According to outside chest CT or , the patient has "numerous small cutaneous nodules along the thorax suggestive of neurofibromatosis." According to the outside pathology report, the patient has a clinical history of neurofibromatosis. Also, by CT the chest wall mass is 7.7 cm in the lateral wall and was interpreted as being compatible with a neural tumor, possibly a malignant peripheral nerve sheath tumor. Taken together with the clinical history and radiological findings, the histomorphology and immunohistochemistry profile of this left chest wall mass is consistent with a malignant peripheral nerve sheath tumor.

[page 2 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

History:

The patient is a [REDACTED] year-old woman with a left chest wall mass.

Materials Received:

Received are ten slides labeled [REDACTED] accompanied by a corresponding pathology report. Four slides are digitally scanned for our records. All materials are returned to the referring institution.

END OF REPORT

Page 2 of 2

Page: 2 of 2

Printed from

Source: NCI Genomic Data Commons file 2c1b4a1f-3b0b-49c0-beb3-135e5cb9a935 (TCGA-SI-A71Q.1340AFF1-A69A-4708-A7B1-90FE3827F42D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).